Somatic mutation profile of tumor specimen TCGA-CV-7427-01A (aliquot TCGA-CV-7427-01A-11D-2078-08) from TCGA case TCGA-CV-7427, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 73.9 years (26,975 days).
Specimen TCGA-CV-7427-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fccab1a8-c0cd-4557-8860-ac4ea95ca6c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7427-10A (Blood Derived Normal), aliquot TCGA-CV-7427-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b9dee4bf-acff-45a6-b11a-10edb329dbfa

The open-access MAF lists 466 somatic variants for this specimen: 353 protein-altering or splice-affecting, 104 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 310, Silent 104, Nonsense Mutation 34, Intron 4, Frame Shift Del 3, Splice Site 2, Frame Shift Ins 2, Splice Region 2, RNA 2, 3'Flank 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.4195G>A p.D1399N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519889, COSV54325045, COSV54326888, COSV54344606; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- RAC1 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 23/86 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519874, COSV61821563, COSV61823187; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TMEM131 | c.3955G>C p.E1319Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.26); PolyPhen benign (0.01); catalogued as COSV51770253, COSV51770622, COSV51771645; called by muse, mutect2, varscan2
- ABCD2 | c.2145G>C p.Q715H | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV100429533; called by muse, mutect2, varscan2
- AC004593.2 | c.1570G>A p.D524N | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99765209; called by muse, mutect2, varscan2
- ACACB | c.1353G>C p.L451F | Missense Mutation (SNP) | VAF 142/329 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs1325577547, COSV100622982; called by muse, mutect2, varscan2
- ADAM11 | c.1933G>A p.D645N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99567513; called by muse, mutect2, varscan2
- ADAMTS10 | c.2701G>A p.D901N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV54357474, COSV54358510; called by muse, mutect2, varscan2
- ADCY6 | c.955C>G p.Q319E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV100326666, COSV100326991; called by muse, mutect2
- ADGRA2 | c.555-1G>T p.X185_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100178043; called by muse, mutect2, varscan2
- ADGRL3 | c.1454C>G p.S485C (on ENST00000506720 / NM_001322402.2; = p.S417C on NM_015236.6) | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as COSV101546984, COSV101547194; called by mutect2, varscan2
- ADNP | c.568C>G p.Q190E | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.404); catalogued as COSV100823765; called by muse, mutect2, varscan2
- ADPRHL1 | c.746A>G p.D249G | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100733435; called by muse, mutect2, varscan2
- AGMAT | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV65436427; called by muse, mutect2, varscan2
- AHNAK | c.10732G>A p.D3578N | Missense Mutation (SNP) | VAF 57/224 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV99947779; called by muse, mutect2, varscan2
- AHNAK | c.7461G>C p.M2487I | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57210600, COSV99947783; called by muse, mutect2, varscan2
- AHNAK | c.3688G>C p.E1230Q | Missense Mutation (SNP) | VAF 94/396 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV99947802; called by muse, mutect2, varscan2
- AHNAK | c.3103G>C p.D1035H | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99947543, COSV99947804; called by muse, mutect2, varscan2
- AKAP11 | c.3958C>G p.L1320V | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.096); catalogued as COSV50297359; called by mutect2, varscan2
- AL669918.1 | c.2315G>A p.R772K | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.138); catalogued as COSV101441050; called by muse, mutect2, varscan2
- ANGPTL2 | c.1456C>T p.R486* | Nonsense Mutation (SNP) | VAF 27/153 reads (18%) | catalogued as COSV52221443; called by muse, mutect2, varscan2
- ANKRD12 | c.3179C>G p.S1060* | Nonsense Mutation (SNP) | VAF 28/145 reads (19%) | catalogued as COSV100041426; called by muse, mutect2, varscan2
- APOL1 | c.987G>C p.M329I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100046113; called by muse, mutect2, varscan2
- ARFGEF2 | c.942G>C p.E314D | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV100904286; called by muse, mutect2, varscan2
- ARHGAP25 | c.979G>A p.E327K (on ENST00000409202 / NM_001007231.3; = p.E319K on NM_014882.3) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs752930735, COSV54901682; called by muse, mutect2, varscan2
- ARHGAP31 | c.4330G>C p.E1444Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99957208; called by muse, mutect2, varscan2
- ARHGAP6 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.131); catalogued as rs748125411, COSV100272954, COSV57294273; called by muse, mutect2, varscan2
- ARMCX2 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 24/95 reads (25%) | catalogued as COSV100168174; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1063C>T p.P355S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.31); catalogued as COSV100771917; called by muse, mutect2
- ARPC1B | c.1113C>G p.I371M | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV99402952; called by muse, mutect2, varscan2
- ASTN2 | c.964C>G p.L322V | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.312); catalogued as rs1386299430, COSV100528087; called by muse, mutect2, varscan2
- ASXL2 | c.4076C>T p.S1359L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99711249; called by muse, mutect2, varscan2
- ATP8A2 | c.917G>C p.R306T | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV99681664, COSV99682258; called by muse, mutect2
- ATP8B1 | c.1208C>G p.S403C | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as CM024742, COSV99377340; called by muse, mutect2, varscan2
- AVL9 | c.1458G>C p.E486D | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as rs1562797841, COSV100594653; called by muse, mutect2, varscan2
- BBS2 | c.1195C>G p.H399D | Missense Mutation (SNP) | VAF 38/173 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as COSV99802464; called by muse, mutect2, varscan2
- BCAR3 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV99550822; called by muse, mutect2
- BDP1 | c.6742G>A p.E2248K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV100703168; called by muse, mutect2, varscan2
- BMP6 | c.946C>G p.L316V | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.506); catalogued as rs147293908, COSV51664191, COSV99307050; called by muse, mutect2, varscan2
- C1orf158 | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.31); PolyPhen probably damaging (1); catalogued as COSV99847319; called by muse, mutect2, varscan2
- C8orf34 | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV100298390; called by muse, mutect2, varscan2
- CA14 | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs369995029; called by muse, mutect2, varscan2
- CACNA1A | c.4939G>A p.D1647N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1064795531, COSV100802545; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNA1G | c.405G>C p.K135N | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100661904; called by muse, mutect2, varscan2
- CACNA2D1 | c.2395G>A p.E799K (on ENST00000356253 / NM_001366867.1; = p.E787K on NM_000722.4) | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100666722, COSV62392774; called by muse, mutect2, varscan2
- CAND1 | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as COSV101607321; called by muse, mutect2, varscan2
- CCDC113 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.172); catalogued as COSV99540987; called by muse, mutect2, varscan2
- CCDC174 | c.528G>A p.M176I | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV100358607; called by muse, mutect2
- CCDC27 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV53899533; called by muse, mutect2
- CCDC40 | c.2808G>A p.M936I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100884260; called by muse, mutect2
- CCDC88A | c.2698G>A p.D900N | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV99710530; called by muse, mutect2
- CD1E | c.167C>T p.S56L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs1163912098, COSV100937011; called by muse, mutect2, varscan2
- CD2BP2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 65/272 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200106085, COSV99977120; called by muse, mutect2, varscan2
- CD84 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100246054; called by muse, mutect2, varscan2
- CDC16 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV99372953; called by muse, mutect2
- CDC6 | c.1023G>C p.L341F | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV99266594; called by muse, mutect2, varscan2
- CENPI | c.1072G>C p.E358Q | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.863); catalogued as COSV99515458; called by muse, mutect2, varscan2
- CFAP70 | c.2369G>C p.R790T | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100160649; called by muse, mutect2, varscan2
- CFL1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as COSV100354083; called by muse, mutect2, varscan2
- CHST10 | c.549C>G p.F183L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.637); catalogued as COSV99959019; called by muse, mutect2, varscan2
- CILP | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.239); catalogued as COSV99973502; called by muse, mutect2, varscan2
- CKMT1B | c.1166G>C p.G389A | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100294580; called by muse, mutect2, varscan2
- CLCA1 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.363); catalogued as COSV99322470; called by muse, mutect2, varscan2
- CLPX | c.494C>G p.P165R | Missense Mutation (SNP) | VAF 60/213 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.757); catalogued as COSV100269510; called by muse, mutect2, varscan2
- CNTNAP1 | c.2136C>G p.I712M | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as rs1238108293, COSV99226504; called by muse, mutect2, varscan2
- COG4 | c.205G>C p.E69Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.311); catalogued as COSV100091838; called by muse, mutect2
- COL24A1 | c.3764G>A p.G1255E | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993449; called by muse, mutect2, varscan2
- COL4A2 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847368; called by muse, mutect2, varscan2
- CPEB1 | c.1279G>T p.E427* (on ENST00000617958; = p.E362* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as COSV55617424, COSV99917749; called by muse, mutect2, varscan2
- CPNE7 | c.1282G>A p.D428N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99254889; called by muse, mutect2, varscan2
- CSDE1 | c.107C>A p.S36Y | Missense Mutation (SNP) | VAF 102/379 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99795164; called by muse, mutect2, varscan2
- CSPP1 | c.592G>C p.E198Q (on ENST00000676605; = p.E157Q on NM_024790.6) | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.275); catalogued as COSV99138656, COSV99139770; called by muse, mutect2, varscan2
- CSRNP3 | c.597G>T p.K199N | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100085872; called by muse, mutect2, varscan2
- CWF19L1 | c.969G>T p.Q323H | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as COSV100821532; called by muse, mutect2, varscan2
- CXCL3 | c.157C>T p.H53Y | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99932802; called by muse, mutect2, varscan2
- CYP2C9 | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV99582776; called by muse, mutect2, varscan2
- DAAM1 | c.2426C>T p.A809V | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs540791565, COSV100658451; called by muse, mutect2, varscan2
- DCUN1D1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as COSV99489913; called by muse, mutect2, varscan2
- DDX24 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); catalogued as COSV100427970; called by muse, mutect2, varscan2
- DHTKD1 | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.295); catalogued as COSV99536545; called by muse, mutect2
- DKK3 | c.580C>T p.H194Y | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV100485030; called by muse, mutect2, varscan2
- DMD | c.6466C>A p.Q2156K | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.275); catalogued as COSV58907431; called by muse, mutect2, varscan2
- DNAH11 | c.4927G>T p.G1643* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as COSV100179424; called by muse, mutect2, varscan2
- DNAJA1 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.082); catalogued as COSV100438527; called by muse, mutect2, varscan2
- DNM2 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV100117334; called by muse, mutect2, varscan2
- DOK6 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101234538, COSV66933467; called by muse, mutect2
- DOK6 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.023); catalogued as COSV101234539; called by muse, mutect2
- DPPA2 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV101524734, COSV101524770; called by muse, mutect2, varscan2
- DRD1 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV101192466; called by muse, mutect2, varscan2
- DYNC1H1 | c.2852G>C p.G951A | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as COSV100794980; called by muse, mutect2, varscan2
- DZIP3 | c.2287C>T p.Q763* | Nonsense Mutation (SNP) | VAF 10/36 reads (28%) | catalogued as COSV64314753; called by muse, mutect2
- EBNA1BP2 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs181497889, COSV99355985; called by muse, mutect2, varscan2
- EGFR | c.2136C>G p.F712L | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51770806, COSV99291701; called by muse, mutect2, varscan2
- EHMT1 | c.725C>G p.S242C | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV100603942, COSV58376530; called by muse, mutect2, varscan2
- EIF2AK1 | c.288G>C p.Q96H | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV52240385; called by muse, mutect2, varscan2
- EIF3G | c.758C>A p.T253N | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.171); catalogued as COSV99461379; called by muse, mutect2, varscan2
- EIF4G1 | c.1516C>G p.Q506E (on ENST00000346169 / NM_198241.3; = p.Q310E on NM_004953.5) | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.044); catalogued as COSV100071899, COSV59989895; called by muse, varscan2
- EIF4G1 | c.3259C>T p.P1087S (on ENST00000346169 / NM_198241.3; = p.P892S on NM_004953.5) | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100071901; called by muse, mutect2, varscan2
- ELOA2 | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV99796813; called by muse, mutect2, varscan2
- EML1 | c.2248G>C p.E750Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV51753021, COSV99215097; called by muse, varscan2
- ERICH3 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as COSV58609878, COSV58615836; called by muse, mutect2, varscan2
- ERP44 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV99316460; called by muse, mutect2
- ESX1 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 25/102 reads (25%) | catalogued as COSV101006455; called by muse, mutect2, varscan2
- ESYT1 | c.2176G>C p.D726H | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214654969, COSV99920025; called by muse, mutect2, varscan2
- EXPH5 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV99761705; called by muse, mutect2
- EXTL2 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as COSV64473518; called by muse, mutect2, varscan2
- FAM20B | c.1096G>A p.V366M | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99762398; called by muse, mutect2, varscan2
- FAM50A | c.718G>C p.E240Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99341057; called by muse, mutect2, varscan2
- FAM83B | c.2563C>G p.Q855E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV100174536; called by muse, mutect2, varscan2
- FAT1 | c.2653C>T p.R885* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as COSV71673627; called by muse, mutect2, varscan2
- FBN2 | c.5923G>C p.D1975H | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99327963; called by muse, mutect2, varscan2
- FBXW10 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.494); catalogued as COSV57321109; called by muse, mutect2, varscan2
- FCHSD2 | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV100238520; called by muse, mutect2, varscan2
- FDX1 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99501860; called by muse, mutect2, varscan2
- FGD6 | c.4168G>C p.E1390Q | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.891); catalogued as COSV100676618; called by muse, mutect2, varscan2
- FMR1NB | c.356A>T p.D119V | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.071); catalogued as rs1557188804, COSV100789535; called by muse, mutect2, varscan2
- FXR2 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.009); catalogued as rs750821196, COSV100002089; called by muse, mutect2, varscan2
- FZD6 | c.1253G>C p.G418A | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100708398; called by muse, mutect2, varscan2
- GABRA1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.253); catalogued as COSV99195958; called by muse, mutect2, varscan2
- GABRA1 | c.1285C>A p.L429M | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV99195960; called by muse, mutect2, varscan2
- GAK | c.3554C>T p.S1185F | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100033673; called by muse, mutect2, varscan2
- GBP3 | c.95C>G p.S32C | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99352584; called by muse, mutect2, varscan2
- GBX1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as COSV99880919; called by muse, mutect2, varscan2
- GEMIN4 | c.1744C>G p.L582V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372394762; called by muse, mutect2, varscan2
- GIGYF2 | c.3418G>A p.E1140K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV101004399; called by muse, mutect2, varscan2
- GJA3 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99576402; called by muse, mutect2, varscan2
- GLB1L | c.1534C>G p.L512V | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); catalogued as rs759382989, COSV99850595; called by muse, mutect2, varscan2
- GNL2 | c.1267G>C p.E423Q | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100895006; called by muse, mutect2, varscan2
- GOLGB1 | c.7594G>C p.E2532Q | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.69); catalogued as COSV100510974; called by muse, mutect2, varscan2
- GOLGB1 | c.6967G>C p.D2323H | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV100510976; called by muse, mutect2, varscan2
- GOT2 | c.177G>C p.K59N | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1309507594, COSV99803750; called by muse, mutect2, varscan2
- GPRIN1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV99991689; called by muse, mutect2
- GRIA1 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.516); catalogued as COSV99600301; called by muse, mutect2, varscan2
- GSTA1 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV100575541; called by muse, mutect2, varscan2
- GTPBP4 | c.1797G>C p.K599N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99479212; called by muse, mutect2, varscan2
- H2BC12 | c.84G>C p.K28N | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.291); catalogued as COSV100804691; called by muse, mutect2, varscan2
- H3C6 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.034); catalogued as COSV100839026; called by muse, mutect2, varscan2
- HAS3 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs773346129, COSV54705854; called by muse, mutect2, varscan2
- HCN4 | c.2599G>T p.A867S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV99983804; called by muse, mutect2, varscan2
- HECTD2 | c.768G>C p.Q256H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV99978634; called by muse, mutect2, varscan2
- HEG1 | c.2633G>A p.G878E | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV100230585; called by muse, mutect2, varscan2
- HK2 | c.509C>G p.S170* | Nonsense Mutation (SNP) | VAF 19/127 reads (15%) | catalogued as COSV99309118; called by muse, mutect2, varscan2
- HOOK1 | c.1924G>C p.E642Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.704); catalogued as COSV100969122, COSV64618471; called by muse, mutect2, varscan2
- HOOK2 | c.401G>C p.R134T | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.63); catalogued as COSV53401175, COSV99317613; called by muse, mutect2
- HOXD10 | c.468G>C p.Q156H | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99982777; called by muse, mutect2, varscan2
- HSP90AA1 | c.1624G>A p.V542M | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as COSV53490995; called by muse, mutect2, varscan2
- HSPA4 | c.2351C>G p.S784* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100507694; called by muse, mutect2, varscan2
- IGHMBP2 | c.2352G>C p.K784N | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV99662132; called by mutect2, varscan2
- IL17A | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); catalogued as COSV100391544; called by muse, mutect2, varscan2
- IRAK2 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs769170523, COSV99844035; called by muse, mutect2, varscan2
- IRS1 | c.2815G>A p.E939K | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); catalogued as rs1254174874, COSV100524607, COSV59335663; called by muse, mutect2, varscan2
- IRS4 | c.2594C>T p.S865L | Missense Mutation (SNP) | VAF 65/288 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV100929581; called by muse, varscan2
- ITPRID1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 32/149 reads (21%) | catalogued as COSV100086190, COSV100086550; called by muse, mutect2, varscan2
- JMJD1C | c.6603G>A p.M2201I | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as COSV100550598; called by muse, mutect2, varscan2
- KCNK15 | c.536C>G p.S179W | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100865132; called by muse, mutect2
- KCNK2 | c.925G>A p.D309N (on ENST00000444842 / NM_001017425.3; = p.D294N on NM_014217.4) | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.07); catalogued as COSV101222186, COSV67210953; called by muse, mutect2, varscan2
- KCNS3 | c.1201C>G p.P401A | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV100411243; called by muse, mutect2, varscan2
- KDM6B | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs896246955, COSV99641604; called by muse, mutect2, varscan2
- KIAA1109 | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV99151042; called by muse, mutect2, varscan2
- KIAA1328 | c.1645C>G p.L549V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1297660561, COSV99694414; called by muse, mutect2, varscan2
- KIAA1549L | c.5330C>G p.S1777C (on ENST00000321505; = p.S2074C on NM_012194.3) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100381694, COSV58586399; called by muse, mutect2
- KIAA1841 | c.371C>G p.S124C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV99693785; called by muse, mutect2, varscan2
- KIDINS220 | c.4286C>G p.S1429* | Nonsense Mutation (SNP) | VAF 33/135 reads (24%) | catalogued as COSV99875807; called by muse, mutect2, varscan2
- KIF4B | c.3601G>C p.E1201Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.221); catalogued as COSV101469300; called by muse, mutect2, varscan2
- KLC1 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as rs1381770281, COSV99871557; called by muse, mutect2, varscan2
- KMT2A | c.4755G>A p.M1585I | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100628979; called by muse, mutect2, varscan2
- KPNA6 | c.1242C>G p.I414M | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV101012524; called by muse, mutect2, varscan2
- KRT10 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 32/143 reads (22%) | catalogued as COSV99510104; called by muse, mutect2, varscan2
- KRT74 | c.377A>G p.N126S | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV59774405; called by muse, mutect2, varscan2
- L2HGDH | c.935G>A p.G312E | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99910333; called by muse, varscan2
- LAMTOR4 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV100385509; called by muse, varscan2
- LCP1 | c.114C>G p.F38L | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100549917; called by muse, mutect2, varscan2
- LIPI | c.434G>C p.R145T | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.41); PolyPhen probably damaging (1); catalogued as rs745353795, COSV100753750; called by mutect2, varscan2
- LPAR4 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101425130; called by muse, mutect2, varscan2
- LRP1B | c.8816C>T p.S2939F | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV101257718; called by muse, mutect2, varscan2
- LRP6 | c.3829G>A p.E1277K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.232); catalogued as COSV99743464; called by muse, mutect2, varscan2
- LRRC31 | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as COSV99246755; called by muse, mutect2, varscan2
- LRRC36 | c.1418G>C p.R473T | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.286); catalogued as COSV99338760; called by muse, mutect2, varscan2
- LRRC42 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.915); catalogued as COSV100066197; called by muse, mutect2, varscan2
- MAGEA8 | c.239G>C p.W80S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0.068); catalogued as COSV99674622; called by muse, mutect2, varscan2
- MAP1S | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766897244, COSV100141065; called by muse, mutect2, varscan2
- MAP3K14 | c.376G>T p.E126* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100766502; called by muse, mutect2, varscan2
- MAP9 | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV60905505; called by muse, mutect2, varscan2
- MCC | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100202722; called by muse, mutect2, varscan2
- MEDAG | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100995269; called by muse, mutect2, varscan2
- MRE11 | c.1823C>G p.S608* | Nonsense Mutation (SNP) | VAF 36/141 reads (26%) | catalogued as COSV100119734; called by muse, mutect2, varscan2
- MROH5 | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.874); catalogued as COSV101436009; called by muse, mutect2, varscan2
- MRPL41 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs935435495, COSV99480855; called by muse, mutect2, varscan2
- MSRB3 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as COSV100377959; called by muse, mutect2
- MTF1 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV100886508; called by muse, mutect2, varscan2
- MTIF3 | c.669C>G p.F223L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100820197; called by muse, mutect2, varscan2
- MTNR1A | c.502C>G p.L168V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV100208216; called by muse, mutect2, varscan2
- MUC6 | c.6376C>T p.Q2126* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV101424628; called by muse, mutect2
- MYCBP2 | c.12982G>A p.E4328K (on ENST00000357337; = p.E4366K on NM_015057.5) | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV100630522; called by muse, mutect2, varscan2
- MYCBP2 | c.7846G>C p.E2616Q (on ENST00000357337; = p.E2654Q on NM_015057.5) | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100630524, COSV62018855, COSV62033793; called by muse, mutect2, varscan2
- MYO1F | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.045); catalogued as COSV100596751; called by muse, mutect2, varscan2
- MYO9B | c.4251G>C p.K1417N | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV101261596; called by muse, mutect2
- MYPN | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.96); PolyPhen benign (0.014); catalogued as rs1472208495, COSV100590043; called by muse, mutect2, varscan2
- NANOG | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.189); catalogued as COSV99981588; called by muse, mutect2
- NAP1L3 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV100220418; called by muse, mutect2, varscan2
- NBAS | c.5612C>T p.P1871L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs372931827; called by muse, mutect2, varscan2
- NBEAL1 | c.4283C>G p.S1428C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV71375260; called by muse, mutect2, varscan2
- NCOR1 | c.6916G>A p.E2306K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); catalogued as COSV99246231; called by muse, mutect2
- NDUFA5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100864245; called by muse, mutect2, varscan2
- NEURL4 | c.1331C>G p.S444C | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV100224322; called by muse, mutect2, varscan2
- NFATC2 | c.2296C>T p.Q766* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV101044187; called by muse, mutect2, varscan2
- NIPBL | c.1252C>G p.Q418E | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.585); catalogued as rs1561102274, COSV56945419, COSV99240853; called by muse, mutect2, varscan2
- NMT1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV99364817; called by muse, mutect2
- NOTCH1 | c.3267G>A p.W1089* | Nonsense Mutation (SNP) | VAF 32/108 reads (30%) | catalogued as COSV99488542; called by muse, mutect2, varscan2
- NPIPA1 | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs768939993; called by muse, mutect2
- NR1D2 | c.805C>G p.Q269E | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV56991549; called by muse, mutect2, varscan2
- NRSN1 | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV101027299; called by muse, mutect2, varscan2
- NSRP1 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99898418; called by muse, mutect2, varscan2
- NTM | c.518C>G p.S173C | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66199916; called by muse, mutect2, varscan2
- OIP5 | c.597G>C p.L199= | Splice Region (SNP) | VAF 20/78 reads (26%) | catalogued as COSV99593062; called by muse, mutect2
- OLFM1 | c.629G>C p.R210T (on ENST00000371793 / NM_001282611.2; = p.R192T on NM_014279.5) | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV52963433, COSV99423939; called by muse, mutect2, varscan2
- OXLD1 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as COSV100235722, COSV100235863; called by muse, mutect2, varscan2
- P2RY10 | c.216C>G p.F72L | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50681525, COSV99409013, COSV99409162; called by muse, mutect2, varscan2
- PAG1 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99597511; called by muse, mutect2
- PARP4 | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs373111528; called by muse, mutect2, varscan2
- PCDH17 | c.398C>G p.S133C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100931692; called by muse, mutect2, varscan2
- PCDHB15 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.236); catalogued as rs2907300, COSV51096522; called by muse, mutect2, varscan2
- PCDHGA5 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.104); catalogued as COSV99537264; called by muse, mutect2, varscan2
- PCGF3 | c.553C>G p.L185V | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.29); catalogued as COSV100745262, COSV62858693; called by muse, mutect2, varscan2
- PCLO | c.4091G>A p.G1364E | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61653928, COSV61657562; called by muse, mutect2, varscan2
- PEAK1 | c.2279G>A p.R760K | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV100433068; called by muse, mutect2, varscan2
- PGK2 | c.451C>T p.R151* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as rs751234582, COSV59164192; called by muse, mutect2, varscan2
- PHTF2 | c.1288C>G p.Q430E (on ENST00000248550 / NM_001366089.1; = p.Q392E on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99301810; called by mutect2, varscan2
- PI4KA | c.3189G>A p.M1063I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as COSV104372219, COSV99746578; called by muse, mutect2, varscan2
- PIM3 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as rs1569200319, COSV100638424, COSV100638443; called by muse, mutect2, varscan2
- PLEKHB1 | c.677G>C p.G226A | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99909537; called by muse, mutect2, varscan2
- PLXNB2 | c.1836C>G p.F612L | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100834093; called by muse, mutect2, varscan2
- PML | c.1553C>T p.S518L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99167289; called by muse, mutect2, varscan2
- POLG | c.3166G>A p.E1056K | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.572); catalogued as COSV99174815; called by muse, mutect2
- PRAMEF10 | c.1149C>A p.N383K | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1170540103; called by muse, mutect2
- PRAMEF15 | c.812G>A p.C271Y | Missense Mutation (SNP) | VAF 61/368 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1280146914; called by muse, mutect2, varscan2
- PRC1 | c.1819G>C p.D607H | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV100727143; called by muse, mutect2, varscan2
- PRPH2 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370994796; called by muse, mutect2, varscan2
- PRPS2 | c.573G>C p.L191F | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); catalogued as COSV101037608; called by muse, mutect2, varscan2
- PTDSS1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 33/226 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.389); catalogued as COSV61265162; called by muse, mutect2, varscan2
- PTPRB | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV99717646; called by muse, mutect2, varscan2
- PTPRF | c.2809G>T p.D937Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV100740951; called by muse, varscan2
- PTPRF | c.2908G>C p.D970H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV100740952; called by muse, mutect2, varscan2
- PTPRM | c.3049G>C p.E1017Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs906394213, COSV59859196, COSV59872040; called by muse, mutect2, varscan2
- RAB36 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs748932299, COSV99572128; called by muse, mutect2, varscan2
- RAD18 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99368491; called by muse, mutect2, varscan2
- RASA2 | c.593C>T p.S198F | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99656223; called by muse, mutect2, varscan2
- REV3L | c.6365C>T p.S2122F | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100725253; called by muse, mutect2, varscan2
- RFX2 | c.1261G>A p.E421K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.161); catalogued as rs371410292; called by muse, mutect2, varscan2
- RGS12 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs777859863, COSV100375694; called by muse, mutect2, varscan2
- RNF213 | c.6213C>G p.F2071L | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1035740297, COSV60399089; called by muse, mutect2, varscan2
- RPN2 | c.358T>A p.S120T | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.912); catalogued as COSV99411792; called by muse, mutect2, varscan2
- RPN2 | c.359C>A p.S120* | Nonsense Mutation (SNP) | VAF 22/97 reads (23%) | catalogued as COSV99411795; called by muse, mutect2, varscan2
- RRP8 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs1486842993, COSV99601930; called by muse, mutect2, varscan2
- RSKR | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99972125; called by muse, mutect2
- RUFY2 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | catalogued as rs1030341042, COSV61190793; called by muse, mutect2, varscan2
- S100A2 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.327); catalogued as COSV100905950; called by muse, mutect2, varscan2
- SACS | c.5302C>G p.H1768D | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV101207484; called by muse, mutect2, varscan2
- SAFB2 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99385775; called by muse, mutect2
- SASH3 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100795236; called by muse, mutect2, varscan2
- SBNO2 | c.3097C>T p.Q1033* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100684632; called by muse, mutect2, varscan2
- SECISBP2L | c.428T>C p.I143T | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV99960437; called by muse, mutect2, varscan2
- SERPINB6 | c.388C>G p.Q130E (on ENST00000612421 / NM_001271823.2; = p.Q111E on NM_004568.6) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.042); catalogued as COSV100177511; called by muse, mutect2, varscan2
- SERTAD4 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.188); catalogued as COSV100882626; called by muse, mutect2, varscan2
- SETD3 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100075122; called by muse, mutect2
- SETD7 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as rs747992989, COSV56800000; called by muse, mutect2, varscan2
- SETDB1 | c.2086G>A p.E696K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV54979770, COSV54984186; called by muse, mutect2, varscan2
- SF1 | c.803C>G p.S268* | Nonsense Mutation (SNP) | VAF 16/103 reads (16%) | catalogued as COSV57114322, COSV99918405; called by muse, mutect2, varscan2
- SI | c.3766C>T p.Q1256* | Nonsense Mutation (SNP) | VAF 27/111 reads (24%) | catalogued as COSV100013884, COSV100015767, COSV52264857; called by muse, mutect2, varscan2
- SIRPB1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.411); catalogued as COSV99498416; called by muse, mutect2
- SLC10A4 | c.1009G>C p.G337R | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99906905; called by muse, mutect2, varscan2
- SLC17A3 | c.239C>G p.S80C | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV100399039, COSV100399228, COSV57760051; called by muse, mutect2
- SLC23A1 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs765188125, COSV104372248, COSV99497279; called by muse, mutect2, varscan2
- SLC24A2 | c.1038C>G p.I346M | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99646763; called by muse, mutect2, varscan2
- SLC5A2 | c.999G>C p.M333I | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100393219; called by muse, mutect2, varscan2
- SLC8A3 | c.1915G>C p.D639H (on ENST00000381269 / NM_183002.3; = p.X637_splice on NM_033262.4) | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.168); catalogued as COSV99385554; called by muse, mutect2, varscan2
- SMAD3 | c.1247C>T p.S416F | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV59286689; called by muse, mutect2, varscan2
- SMAD5 | c.427C>T p.R143C | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484200210; called by muse, mutect2
- SNAI2 | c.564G>C p.K188N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.119); catalogued as COSV50078823, COSV99194964; called by muse, mutect2, varscan2
- SNTB1 | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1258511683, COSV101180016; called by muse, mutect2, varscan2
- SNX27 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100919054; called by muse, mutect2, varscan2
- SPECC1L | c.2765C>T p.S922L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.855); catalogued as COSV100062495; called by muse, mutect2, varscan2
- SPIN4 | c.508G>A p.D170N | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100633365; called by muse, mutect2, varscan2
- SPINK9 | c.54C>T p.F18= | Splice Region (SNP) | VAF 9/97 reads (9%) | catalogued as COSV64958048; called by muse, mutect2, varscan2
- SPTA1 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100935071, COSV63748689; called by muse, mutect2, varscan2
- SREBF1 | c.2256G>C p.Q752H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.035); catalogued as COSV99888959; called by muse, mutect2
- SREK1 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV99398625; called by muse, mutect2, varscan2
- SRPK2 | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.954); catalogued as COSV100624076; called by muse, mutect2, varscan2
- STAT1 | c.882C>G p.I294M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV100699996; called by muse, varscan2
- STAT5B | c.1771G>A p.D591N | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99511000; called by muse, mutect2, varscan2
- STK16 | c.307-1G>C p.X103_splice | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99850598; called by muse, mutect2, varscan2
- STK31 | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV100669472; called by muse, mutect2, varscan2
- SULT1E1 | c.612A>G p.I204M | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV99894999; called by muse, mutect2, varscan2
- SUPV3L1 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.479); catalogued as COSV100669705; called by muse, mutect2, varscan2
- SYNE2 | c.20344G>C p.E6782Q | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs199923651, COSV100647811; called by muse, mutect2
- SYTL5 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV52901148, COSV52906573; called by muse, mutect2, varscan2
- TAF2 | c.928G>A p.D310N | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as COSV100978716, COSV100978781; called by muse, mutect2
- TARDBP | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as COSV99534268; called by muse, mutect2, varscan2
- TAS2R46 | c.766G>C p.E256Q | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101114947; called by muse, mutect2
- TBP | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs756227958, COSV57830402; called by muse, mutect2, varscan2
- TDRD6 | c.4348G>T p.E1450* | Nonsense Mutation (SNP) | VAF 38/154 reads (25%) | catalogued as COSV100287711, COSV60179481; called by muse, mutect2, varscan2
- TEPP | c.776C>G p.S259C (on ENST00000441824 / NM_199456.3; = p.S286C on NM_199046.3) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52043865, COSV99333063; called by muse, mutect2, varscan2
- TFAP2A | c.578C>G p.S193C (on ENST00000482890; = p.S185C on NM_001032280.3) | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV60232811, COSV60236395; called by muse, mutect2, varscan2
- THBS2 | c.2866G>C p.E956Q | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.681); catalogued as COSV100827920; called by muse, mutect2, varscan2
- TMCC2 | c.1093G>C p.E365Q | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV100319391; called by muse, mutect2, varscan2
- TMEM106B | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.179); catalogued as rs1338738117, COSV101188826; called by muse, varscan2
- TMEM209 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.076); catalogued as rs200051270, COSV100390452; called by muse, mutect2, varscan2
- TNFRSF4 | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99767680; called by muse, mutect2, varscan2
- TNR | c.3739G>T p.E1247* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV99689900; called by muse, mutect2, varscan2
- TOR1B | c.439C>T p.H147Y | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99400200; called by muse, mutect2, varscan2
- TREM1 | c.345C>G p.I115M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99776224; called by muse, mutect2, varscan2
- TRPV5 | c.1961C>G p.S654* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV99520599; called by muse, mutect2, varscan2
- TSPAN11 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); catalogued as COSV99666940; called by muse, mutect2, varscan2
- TTC14 | c.1976G>T p.R659I | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99869163; called by muse, mutect2, varscan2
- TTC16 | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777558099, COSV100959869; called by muse, mutect2, varscan2
- TUBD1 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV100360107; called by muse, mutect2
- TUBGCP6 | c.5007C>G p.F1669L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV50561443, COSV99955675; called by muse, mutect2, varscan2
- TXNDC2 | c.886G>A p.E296K (on ENST00000306084 / NM_001098529.2; = p.E229K on NM_032243.6) | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.094); catalogued as rs1310794866, COSV100046211; called by muse, mutect2, varscan2
- UBC | c.94G>C p.D32H | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100299006; called by muse, mutect2
- UBE2D2 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99551389; called by muse, mutect2, varscan2
- UBR4 | c.7192G>A p.D2398N | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs55848569, COSV100920959; called by muse, mutect2, varscan2
- VAV1 | c.1624C>G p.Q542E | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV58379005; called by muse, mutect2, varscan2
- VIT | c.1081G>C p.E361Q (on ENST00000389975 / NM_001177969.1; = p.E376Q on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV101007426; called by muse, mutect2, varscan2
- VPS13B | c.7153G>A p.E2385K | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as CM062028, COSV62157328; called by muse, mutect2, varscan2
- VPS53 | c.1807C>T p.Q603* (on ENST00000571805 / NM_001366253.2; = p.Q574* on NM_018289.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99346166; called by muse, mutect2
- WDR37 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99579757; called by muse, mutect2, varscan2
- WDR44 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.367); catalogued as COSV99561592; called by muse, mutect2, varscan2
- WEE2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV101285185; called by muse, mutect2, varscan2
- WNT4 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.02); catalogued as rs1300290034, COSV51604976, COSV99268692; called by muse, mutect2
- WTAP | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100493350; called by muse, mutect2, varscan2
- XKR6 | c.1879G>C p.D627H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100440762; called by muse, mutect2, varscan2
- XYLT1 | c.1468G>C p.D490H | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99760405, COSV99762006; called by muse, mutect2, varscan2
- YARS1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100993431; called by muse, mutect2, varscan2
- YLPM1 | c.5358G>C p.R1786S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV99459840; called by muse, mutect2, varscan2
- ZBTB22 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.699); catalogued as COSV99802187; called by muse, mutect2, varscan2
- ZC3H12A | c.421G>C p.D141H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100897720; called by muse, mutect2, varscan2
- ZCCHC14 | c.880C>G p.Q294E (on ENST00000268616; = p.Q431E on NM_015144.3) | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs1452873352, COSV99234028; called by muse, mutect2, varscan2
- ZFP37 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV100953278; called by muse, mutect2, varscan2
- ZNF136 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100678008; called by muse, mutect2, varscan2
- ZNF208 | c.2066G>C p.G689A | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101237041; called by muse, mutect2, varscan2
- ZNF300 | c.1405G>C p.E469Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as COSV99199891; called by muse, mutect2, varscan2
- ZNF345 | c.704G>C p.C235S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100080318; called by muse, mutect2, varscan2
- ZNF418 | c.295G>A p.D99N | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101268943; called by muse, mutect2, varscan2
- ZNF44 | c.1355C>T p.S452F (on ENST00000356109 / NM_001164276.2; = p.S404F on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV100633582; called by muse, mutect2, varscan2
- ZNF444 | c.137G>T p.R46L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.982); catalogued as COSV100442651; called by muse, mutect2, varscan2
- ZNF559-ZNF177 | c.672G>C p.K224N | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.381); catalogued as COSV100606152; called by muse, mutect2, varscan2
- ZNF678 | c.606T>G p.I202M | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs1326735522, COSV100652799; called by muse, mutect2, varscan2
- FAT1 | c.4478dup p.Q1494Afs*4 | Frame Shift Ins (INS) | VAF 9/55 reads (16%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- IFT81 | c.1420_1423delinsAAA p.E474Kfs*5 | Frame Shift Del (DEL) | VAF 29/119 reads (24%) | called by pindel, varscan2*
- LONP2 | c.327del p.I110Lfs*5 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.3330del p.R1111Gfs*96 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | called by mutect2, pindel, varscan2
- TMPRSS15 | c.1060dup p.C354Lfs*9 | Frame Shift Ins (INS) | VAF 22/112 reads (20%) | called by mutect2, pindel, varscan2
- ABCB1 | c.1245G>C p.L415= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV55952244, COSV55966446; called by muse, mutect2, varscan2
- ABCD1 | c.1680G>A p.P560= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs782005164, COSV99497643; called by muse, mutect2, varscan2
- ACSS3 | c.1489C>A p.R497= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV99698934; called by muse, mutect2
- ADAM15 | c.1888C>T p.L630= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99665035; called by muse, mutect2, varscan2
- AHNAK | c.15477G>C p.L5159= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV99947773, COSV99948743; called by muse, mutect2, varscan2
- AHNAK | c.4140G>A p.L1380= | Silent (SNP) | VAF 91/351 reads (26%) | catalogued as COSV99947795; called by muse, mutect2, varscan2
- AIG1 | c.354G>A p.P118= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as rs751681589, COSV51636810; called by muse, mutect2, varscan2
- ALAS1 | c.309C>A p.G103= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- AP3D1 | c.2874C>T p.S958= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs751570038, COSV100642736; called by muse, mutect2, varscan2
- ASXL1 | c.1830C>T p.G610= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs199829982; called by mutect2, varscan2
- BIRC3 | c.471G>A p.L157= | Silent (SNP) | VAF 51/214 reads (24%) | catalogued as COSV54815162, COSV99679966; called by muse, mutect2, varscan2
- BIRC6 | c.576C>T p.F192= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as COSV101428345; called by muse, mutect2
- CACNA1D | c.5037C>T p.F1679= (on ENST00000350061 / NM_001128840.3; = p.F1699= on NM_000720.4) | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV99858386; called by muse, mutect2, varscan2
- CALCOCO2 | c.492C>A p.I164= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV51952629, COSV99363799; called by muse, mutect2, varscan2
- CCDC170 | c.1995G>A p.V665= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as COSV99498497; called by muse, mutect2
- CETP | c.1314C>T p.V438= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99570056; called by muse, mutect2
- CLSTN1 | c.1971G>C p.L657= (on ENST00000377298 / NM_001009566.3; = p.L647= on NM_014944.4) | Silent (SNP) | VAF 35/161 reads (22%) | catalogued as COSV100790597; called by muse, mutect2, varscan2
- CNDP2 | c.993G>A p.V331= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100159134; called by muse, varscan2
- COL15A1 | c.1086G>C p.A362= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV100897763; called by muse, mutect2, varscan2
- COL6A2 | c.2316C>G p.L772= | Silent (SNP) | VAF 51/208 reads (25%) | catalogued as COSV100153642; called by muse, mutect2, varscan2
- COPA | c.1038C>T p.F346= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV99615799; called by muse, mutect2, varscan2
- CR2 | c.990G>A p.Q330= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV65509441; called by muse, mutect2, varscan2
- CRISP3 | c.276G>A p.L92= (on ENST00000371159 / NM_001368123.1; = p.L74= on NM_006061.4) | Silent (SNP) | VAF 48/151 reads (32%) | catalogued as COSV99538980; called by muse, mutect2, varscan2
- CYB561 | c.426C>T p.F142= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV100669121; called by muse, mutect2, varscan2
- DLL3 | c.36G>A p.Q12= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV99219141; called by muse, mutect2, varscan2
- DRD2 | c.1185G>A p.L395= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100669722; called by muse, mutect2, varscan2
- DRP2 | c.1746C>T p.V582= | Silent (SNP) | VAF 26/127 reads (20%) | catalogued as COSV100871927; called by muse, mutect2, varscan2
- EIF4G1 | c.1452C>T p.L484= (on ENST00000346169 / NM_198241.3; = p.L288= on NM_004953.5) | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100071897; called by muse, varscan2
- EMILIN2 | c.2922C>T p.N974= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs775932549, COSV99598577; called by muse, mutect2, varscan2
- ERF | c.516C>T p.L172= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs760238666, COSV99724404; called by muse, mutect2, varscan2
- FAM114A2 | c.972C>T p.S324= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV100697710; called by muse, mutect2, varscan2
- FAM214A | c.78G>A p.L26= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV55922802, COSV99958028; called by muse, mutect2, varscan2
- FBXL17 | c.1368C>G p.L456= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs758934458, COSV100671638; called by muse, mutect2, varscan2
- FBXO21 | c.1224G>A p.L408= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as rs764977519, COSV57975242; called by muse, mutect2, varscan2
- FGR | c.870G>A p.V290= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100925837, COSV99059856; called by muse, mutect2
- FKBP10 | c.774G>C p.L258= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV100387886; called by muse, mutect2, varscan2
- FOXD4 | c.231C>T p.S77= | Silent (SNP) | VAF 44/171 reads (26%) | catalogued as rs763894392, COSV58703372; called by muse, varscan2
- FPGS | c.693C>T p.L231= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100948822; called by muse, mutect2
- GPR101 | c.543C>G p.L181= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99981449; called by muse, mutect2, varscan2
- H1-1 | c.501G>A p.K167= | Silent (SNP) | VAF 43/214 reads (20%) | catalogued as rs761802965, COSV99772061; called by muse, mutect2, varscan2
- HCN4 | c.2355C>T p.A785= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs554689537, COSV99983806; called by muse, mutect2, varscan2
- HDLBP | c.906G>C p.V302= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as COSV100190791, COSV60498990; called by muse, mutect2, varscan2
- HLA-A | c.963G>A p.V321= | Silent (SNP) | VAF 46/149 reads (31%) | catalogued as COSV100954454; called by muse, mutect2
- HNF4A | c.660C>T p.L220= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV100291422; called by muse, mutect2, varscan2
- HTRA2 | c.12G>A p.P4= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV51206105, COSV99239704; called by muse, varscan2
- IFNA8 | c.105G>A p.R35= | Silent (SNP) | VAF 31/119 reads (26%) | catalogued as COSV101206905; called by muse, mutect2, varscan2
- IGHV4-34 | c.366G>A p.A122= | Silent (SNP) | VAF 41/188 reads (22%) | catalogued as rs772715869; called by muse, mutect2, varscan2
- KANK4 | c.2949G>A p.L983= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100443221; called by muse, mutect2, varscan2
- KCNC2 | c.1102C>T p.L368= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV100128998, COSV99040668; called by muse, mutect2, varscan2
- KCNH6 | c.1068C>T p.F356= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs774234991, COSV59003343; called by muse, mutect2, varscan2
- KDM6B | c.3498G>A p.V1166= | Silent (SNP) | VAF 42/171 reads (25%) | catalogued as COSV54685876; called by muse, mutect2, varscan2
- LAMA3 | c.5805G>A p.V1935= (on ENST00000313654 / NM_198129.4; = p.V326= on NM_000227.6) | Silent (SNP) | VAF 20/58 reads (34%) | catalogued as rs1330984748, COSV99334975; called by muse, mutect2, varscan2
- LRRN1 | c.861T>C p.L287= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100076350; called by muse, mutect2, varscan2
- LSMEM1 | c.99C>T p.L33= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV57196443; called by muse, mutect2, varscan2
- LTB | c.669C>T p.I223= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV101438048; called by muse, mutect2, varscan2
- MYRIP | c.1002G>A p.K334= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV100219312; called by muse, mutect2, varscan2
- NAA80 | c.216G>T p.L72= (on ENST00000417393 / NM_001200018.2; = p.L94= on NM_012191.4) | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as COSV99807689; called by muse, mutect2, varscan2
- NFKBIL1 | c.534G>A p.Q178= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV101092919; called by muse, mutect2
- NKX3-1 | c.612C>G p.A204= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV101082789; called by muse, mutect2
- NOS2 | c.441C>T p.V147= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as COSV100569689; called by muse, mutect2, varscan2
- NR1D2 | c.966C>T p.F322= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs200679135, COSV100437477; called by muse, mutect2, varscan2
- OR2AT4 | c.870C>G p.L290= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV100532346; called by muse, mutect2, varscan2
- OSM | c.261G>A p.L87= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99304117; called by muse, mutect2, varscan2
- PAGE5 | c.117T>C p.S39= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV99215769; called by muse, mutect2, varscan2
- PGM2L1 | c.1167C>G p.V389= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV99994936; called by muse, mutect2, varscan2
- PHACTR4 | c.675C>T p.V225= (on ENST00000373839 / NM_001350159.2; = p.V235= on NM_023923.4) | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV100868463; called by mutect2, varscan2
- PHLPP1 | c.3777G>A p.Q1259= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as COSV99408421; called by muse, mutect2
- PLA2G2F | c.528C>T p.F176= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs755606679, COSV100907914; called by muse, mutect2, varscan2
- PPIP5K2 | c.366C>T p.I122= | Silent (SNP) | VAF 46/198 reads (23%) | catalogued as COSV100383907; called by muse, mutect2, varscan2
- PPP1R42 | c.270C>G p.L90= | Silent (SNP) | VAF 15/90 reads (17%) | catalogued as COSV100221304; called by muse, mutect2, varscan2
- PRAMEF12 | c.1353C>T p.F451= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV63214850, COSV63215116; called by muse, mutect2, varscan2
- PTPN21 | c.3180C>A p.L1060= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as COSV100162025; called by muse, mutect2, varscan2
- PTPRF | c.2685G>A p.K895= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100740950; called by muse, varscan2
- RASA3 | c.1251G>A p.L417= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV61871726, COSV61874423; called by muse, mutect2, varscan2
- RIPOR1 | c.468C>T p.L156= (on ENST00000379312 / NM_001193522.2; = p.L152= on NM_024519.4) | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV99243185; called by muse, mutect2, varscan2
- SCAP | c.63C>T p.L21= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99652830; called by muse, mutect2, varscan2
- SFRP5 | c.897C>T p.F299= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99823181; called by muse, varscan2
- SGK3 | c.1152G>C p.V384= | Silent (SNP) | VAF 47/107 reads (44%) | catalogued as COSV100616725; called by muse, mutect2, varscan2
- SLC34A2 | c.1389C>T p.I463= | Silent (SNP) | VAF 16/76 reads (21%) | catalogued as rs1039506193, COSV65940540; called by muse, mutect2, varscan2
- SLC3A2 | c.879C>T p.L293= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100101414; called by muse, mutect2, varscan2
- SLITRK3 | c.1665C>G p.V555= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV53846506, COSV99579351; called by muse, mutect2
- SMCR8 | c.957G>A p.L319= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV100329117; called by muse, mutect2, varscan2
- SPATA5 | c.138G>A p.L46= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV99915603; called by muse, mutect2, varscan2
- STAT1 | c.936C>G p.L312= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100699995; called by muse, varscan2
- SUCLA2 | c.345C>T p.L115= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as rs761921467, COSV101074857; called by muse, varscan2
- SUMO3 | c.270G>A p.T90= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs776805257, COSV100254435; called by muse, mutect2, varscan2
- TARS1 | c.567C>T p.L189= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as rs1156970022, COSV99465633, COSV99465970; called by muse, mutect2, varscan2
- TBC1D3L | c.1557C>T p.F519= | Silent (SNP) | VAF 21/123 reads (17%) | called by muse, mutect2, varscan2
- TCTEX1D1 | c.189G>A p.Q63= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as COSV99259179; called by muse, mutect2, varscan2
- TLE2 | c.162G>T p.T54= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99504401; called by muse, mutect2, varscan2
- TMEM141 | c.114C>T p.F38= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as COSV99264411; called by muse, mutect2, varscan2
- TMOD2 | c.447C>T p.F149= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs372217308; called by muse, mutect2, varscan2
- TRIM32 | c.333C>T p.F111= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV57821993; called by muse, mutect2, varscan2
- TRIM4 | c.1365G>A p.G455= | Silent (SNP) | VAF 24/133 reads (18%) | catalogued as COSV100584313; called by muse, mutect2, varscan2
- TRPM6 | c.5385C>T p.L1795= | Silent (SNP) | VAF 54/128 reads (42%) | catalogued as COSV100666451; called by muse, mutect2, varscan2
- TRPM8 | c.2400G>T p.V800= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV100224133; called by muse, mutect2
- TRUB2 | c.105G>C p.L35= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV55957951; called by muse, mutect2, varscan2
- UPP1 | c.921G>T p.L307= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100080758; called by muse, mutect2, varscan2
- WT1 | c.1137C>T p.F379= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs200539928, COSV60067141; called by muse, mutect2, varscan2
- XKR7 | c.1302C>G p.V434= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV101629265, COSV73813373; called by muse, mutect2, varscan2
- YIPF2 | c.294C>T p.I98= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV99450097; called by muse, mutect2, varscan2
- ZNF175 | c.1443G>A p.G481= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV99219535; called by muse, mutect2, varscan2
- ZNF43 | c.522C>T p.F174= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1185642774, COSV61683977; called by muse, mutect2, varscan2
- ZNF609 | c.105C>T p.I35= | Silent (SNP) | VAF 18/84 reads (21%) | catalogued as COSV100441146; called by muse, mutect2, varscan2
- AL133373.3 | n.840G>A | RNA (SNP) | VAF 5/16 reads (31%) | catalogued as rs754625249; called by muse, mutect2
- B4GALNT1 | c.*1867G>A | 3'UTR (SNP) | VAF 22/100 reads (22%) | catalogued as rs778284257, COSV100247177; called by muse, mutect2, varscan2
- CLP1 | chr11:57661438 G>C | 3'Flank (SNP) | VAF 34/88 reads (39%) | catalogued as COSV100239830; called by muse, mutect2, varscan2
- EPS8L1 | c.429+223G>C | Intron (SNP) | VAF 6/29 reads (21%) | catalogued as COSV99136421; called by muse, mutect2
- HOXC11 | c.-1G>A | 5'UTR (SNP) | VAF 9/31 reads (29%) | catalogued as rs867894513, COSV99678331; called by muse, mutect2, varscan2
- KANSL2 | c.973+219C>T | Intron (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100770969; called by muse, varscan2
- SCN3A | c.603-133C>T | Intron (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99327229; called by muse, mutect2, varscan2
- SSPOP | n.2966C>G | RNA (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100022570; called by muse, mutect2, varscan2
- WNK1 | c.2140-2183G>A | Intron (SNP) | VAF 37/310 reads (12%) | catalogued as rs1312282687, COSV100267565; called by muse, mutect2, varscan2
